Gene-level copy-number profile of tumor specimen ALCH-AEO4-TTP1-A from ALCHEMIST case ALCH-AEO4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen ALCH-AEO4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ecc2a911-30b3-477f-8287-985eb722778b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEO4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/7c7b32a5-acdc-4168-bae2-27bf236196ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 17,529; copy number 2: 38,273; copy number 3: 2,483; copy number 4: 62; copy number 6: 1; copy number 8: 13; copy number 9: 4; copy number 10: 1; copy number 18: 8.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–944,581, 1 gene (within-gene range 0–1): SAMD11.
- chr3:57,493,667–57,696,596, 13 genes (within-gene range 0–1): Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT.
- chr3:57,800,056–57,801,448, 1 gene (within-gene range 0–1): PDHA1P1.
- chr9:41,233,755–41,273,997, 3 genes: MIR4477A, RNA5SP530, AL845472.1.
- chr9:130,444,961–130,501,274, 1 gene: ASS1.
- chr9:137,877,782–138,179,774, 5 genes (within-gene range 0–1): CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr22:18,715,815–18,719,341, 1 gene: PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–2,001,470, 7 genes, copy number 6–10: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr16:80,540,734–80,552,514, 2 genes, copy number 9 (within-gene range 3–9): DYNLRB2, AC108097.1.
- chr22:18,361,820–18,653,617, 18 genes, copy number 8–18: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 17,528. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
